MP2PRT case MP2PRT-PARGFF — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/7b3a6173-410a-4270-a55b-410f5c40ea6a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 3 years; Year of birth: 2003.

Diagnoses (1)
1. Common precursor B ALL: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Blood; Site of resection or biopsy: Blood; Age at diagnosis: 3.6 years (1,307 days); Year of diagnosis: 2007; Days to last follow up: 2,683 days (7.3 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: (DC)  2 weeks Dexamethasone during Induction, Capizzi Methotrexate during Interim Maintenance I; Days to treatment start: 2 days; Days to treatment end: 856 days (2.3 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 2,683 days (7.3 years); Disease response: Complete Response; Progression or recurrence: No; Days progression-free: 2,683 days (7.3 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- ETV6 (FISH): Positive.
- KMT2A (FISH): Negative.
- RUNX1 (FISH): Positive.

Other clinical attributes
- Weight: 17.6 kg; Height: 99 cm; BMI: 17.95735129; Body surface area: 12.5174016.

Biospecimens (2 samples)
- Sample MP2PRT-PARGFF-NB1-A: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Sample MP2PRT-PARGFF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
